Gene-level copy-number profile of tumor specimen TCGA-AR-A1AR-01A from TCGA case TCGA-AR-A1AR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.6 years (18,482 days).
Specimen TCGA-AR-A1AR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.c7976361-e689-44f1-9e5a-2a07064f2f95.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98957329-01f6-4939-9fc3-2d541a680cb0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 21,978; copy number 2: 30,105; copy number 3: 7,406; copy number 4: 105; copy number 5: 80; copy number 6: 18; copy number 7: 19; copy number 11: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AR-01A-31D-A134-01): tumor purity 0.54, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:54,609,249–54,771,277, 4 genes: AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 193 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,862,123–42,541,926, 147 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr12:21,131,194–21,541,249, 8 genes, copy number 6 (within-gene range 4–6): SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX.
- chr12:22,395,088–22,690,665, 8 genes, copy number 6: AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1.
- chr12:22,722,229–22,743,091, 2 genes, copy number 6: RPS27P22, AC084819.1.
- chr16:31,032,889–31,095,980, 9 genes, copy number 5: STX4, AC135050.3, AC135050.1, ZNF668, AC135050.4, ZNF646, PRSS53, AC135050.2, VKORC1.
- chr19:8,444,767–9,019,984, 19 genes, copy number 7 (within-gene range 3–7): HNRNPM, PRAM1, ZNF414, MYO1F, AC092316.1, ADAMTS10, AC130469.1, NFILZ, AC243312.1, ACTL9, OR2Z1, RPL23AP78, AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16, BOLA3P2.

Autosomal genes at a single copy (total copy number 1): 21,552. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
